Gene-level copy-number profile of tumor specimen TCGA-L9-A743-01A from TCGA case TCGA-L9-A743, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.9 years (20,780 days).
Specimen TCGA-L9-A743-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.2c2f17c4-f105-435e-874f-14b13f8ac9b4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L9-A743-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8b86ecf6-a9a5-4300-808b-b63d5aea3329

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 179; copy number 1: 23,898; copy number 2: 26,537; copy number 3: 8,028; copy number 4: 651; copy number 5: 369; copy number 6: 107; copy number 7: 50.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L9-A743-01A-43D-A396-01): tumor purity 0.09, ploidy 6.48, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 179 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,098,660–22,824,213, 166 genes (broad region; genes not listed).
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.
- chr9:88,534,033–89,316,703, 11 genes: NXNL2, LINC02843, AL390791.1, MIR4289, PCNPP2, AL772202.1, S1PR3, SHC3, AL353150.1, CKS2, MIR3153.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 526 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:68,282,388–71,489,976, 43 genes, copy number 7 (within-gene range 4–7): COX6B1P7, ELOCP18, AL139413.1, RPE65, DEPDC1, AL138789.1, DEPDC1-AS1, TXNP2, AL035412.1, AL033530.1, AL691520.1, LINC01707, LINC02791, LINC01758, AL359894.1, LRRC7, SGO1P1, AL117353.1, RN7SL538P, PIN1P1, LRRC7-AS1, LRRC40, RN7SL242P, SRSF11, AL353771.1, ANKRD13C, HHLA3, HHLA3-AS1, CTH, Metazoa_SRP, AL354872.1, CHORDC1P5, CASP3P1, LINC01788, AL513285.1, PTGER3, AL031429.1, AL031429.2, ZRANB2-AS1, ZRANB2, MIR186, ZRANB2-AS2, AL358453.1.
- chr5:58,198–2,262,023, 79 genes, copy number 5–6 (broad region; genes not listed).
- chr5:12,574,830–37,377,971, 334 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr5:41,868,975–45,895,970, 70 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 21,477. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
